Somatic mutation profile of tumor specimen TCGA-85-8355-01A (aliquot TCGA-85-8355-01A-11D-2293-08) from TCGA case TCGA-85-8355, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 63.6 years (23,227 days).
Specimen TCGA-85-8355-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e050381-9118-42b3-8f1a-4a78c3799548.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-8355-10A (Blood Derived Normal), aliquot TCGA-85-8355-10A-01D-2293-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/654f584e-4640-4917-8370-63c49e341cae

The open-access MAF lists 224 somatic variants for this specimen: 160 protein-altering or splice-affecting, 56 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 132, Silent 56, Nonsense Mutation 15, Frame Shift Del 5, Splice Site 4, RNA 4, Frame Shift Ins 2, Intron 2, In Frame Del 1, Splice Region 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.251A>G p.D84G | Missense Mutation (SNP) | VAF 7/28 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM014696, COSV58688961, COSV58702489, COSV58705912; called by muse, mutect2, varscan2
- TP53 | c.376-1G>C p.X126_splice | Splice Site (SNP) | VAF 5/33 reads (15%) | hotspot (GDC flag); catalogued as CS1313555, COSV52688618, COSV52749979, COSV52994579, COSV52996344; called by muse, mutect2
- ABCA2 | c.2339G>A p.W780* (on ENST00000614293; = p.W750* on NM_001606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/98 reads (20%) | catalogued as COSV99688102, COSV99688641; called by muse, mutect2, varscan2
- AC098582.1 | c.777G>A p.K259= | Splice Region (SNP) | VAF 5/57 reads (9%) | catalogued as rs1334614738, COSV99986141; called by muse, mutect2
- ADAMTS18 | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99274659; called by muse, mutect2, varscan2
- AGTR2 | c.610T>C p.Y204H | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100903640; called by muse, mutect2, varscan2
- ALOX5 | c.1586C>T p.S529L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV65551304, COSV65552070; called by muse, mutect2, varscan2
- ALX1 | c.259C>A p.P87T | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV100374625; called by muse, mutect2, varscan2
- ALX1 | c.260C>A p.P87H | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV100374627; called by muse, mutect2
- AMOT | c.2414T>G p.L805R (on ENST00000371959 / NM_001113490.1; = p.L396R on NM_133265.3) | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs746405064, COSV100495686; called by muse, mutect2, varscan2
- ANKRD30A | c.703G>T p.D235Y (on ENST00000611781; = p.D179Y on NM_052997.2) | Missense Mutation (SNP) | VAF 50/352 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100654636; called by muse, mutect2, varscan2
- ARGLU1 | c.620A>T p.E207V | Missense Mutation (SNP) | VAF 30/263 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100639798; called by muse, mutect2, varscan2
- ARID1A | c.3871G>T p.E1291* | Nonsense Mutation (SNP) | VAF 13/93 reads (14%) | catalogued as COSV61378502; called by muse, varscan2
- ARL10 | c.619A>G p.I207V | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100119172; called by muse, mutect2, varscan2
- ATP1A3 | c.2453A>G p.D818G (on ENST00000545399 / NM_001256214.2; = p.D805G on NM_152296.5) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100132636; called by muse, mutect2
- BIRC6 | c.1815A>T p.Q605H | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV101429312; called by muse, mutect2, varscan2
- C5AR1 | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV100754077; called by muse, mutect2, varscan2
- CADM3 | c.438C>A p.D146E (on ENST00000368125 / NM_001127173.3; = p.D180E on NM_021189.5) | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV100930461; called by muse, mutect2, varscan2
- CALN1 | c.529G>T p.G177* (on ENST00000329008 / NM_001017440.3; = p.G219* on NM_031468.4) | Nonsense Mutation (SNP) | VAF 24/189 reads (13%) | catalogued as COSV100210008; called by muse, mutect2, varscan2
- CBLIF | c.655A>G p.I219V | Missense Mutation (SNP) | VAF 10/179 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV99951130; called by muse, mutect2
- CC2D1B | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.357); catalogued as COSV99430452; called by mutect2, varscan2
- CCM2 | c.633T>A p.C211* | Nonsense Mutation (SNP) | VAF 10/150 reads (7%) | catalogued as COSV99348245; called by muse, mutect2
- CD300LB | c.512G>A p.W171* | Nonsense Mutation (SNP) | VAF 15/105 reads (14%) | catalogued as COSV58726095; called by muse, mutect2, varscan2
- CDK6 | c.959C>T p.T320I | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.043); catalogued as COSV99721847; called by muse, mutect2, varscan2
- CHRDL1 | c.327C>A p.C109* (on ENST00000372045; = p.C115* on NM_145234.4) | Nonsense Mutation (SNP) | VAF 38/155 reads (25%) | catalogued as COSV99488868; called by muse, mutect2, varscan2
- CHRM2 | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV57765565; called by muse, mutect2, varscan2
- CLVS2 | c.313C>G p.P105A | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51569741, COSV99253768; called by muse, mutect2, varscan2
- CNTNAP2 | c.2324C>A p.T775N | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV100673928, COSV62175891; called by muse, mutect2, varscan2
- CNTNAP5 | c.113T>A p.L38H | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV101444383; called by muse, mutect2, varscan2
- COL11A1 | c.3814G>A p.G1272S | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.1); catalogued as rs1396950266, COSV100618355, COSV62176026; called by muse, mutect2, varscan2
- COL28A1 | c.316C>A p.P106T | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.089); catalogued as COSV101259009; called by muse, mutect2, varscan2
- CPM | c.876G>T p.K292N | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as COSV58033579; called by muse, mutect2
- CRYBG1 | c.2710G>A p.V904M | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as rs754338096, COSV100954642; called by muse, mutect2, varscan2
- CTNNA3 | c.532G>C p.G178R | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.999); catalogued as rs772545551, COSV100373499; called by muse, mutect2
- CTSF | c.749A>T p.N250I | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV100074550; called by muse, mutect2, varscan2
- CYP2C18 | c.768C>G p.D256E | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as COSV99609092; called by muse, mutect2, varscan2
- DCX | c.416C>T p.T139I | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as COSV57566272; called by muse, mutect2, varscan2
- DHX15 | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as COSV100391848; called by muse, mutect2
- DLC1 | c.4114A>G p.I1372V (on ENST00000276297 / NM_001348081.2; = p.I935V on NM_006094.5) | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99360555; called by muse, mutect2, varscan2
- DNAH3 | c.3586C>T p.Q1196* | Nonsense Mutation (SNP) | VAF 5/88 reads (6%) | catalogued as COSV99771365; called by muse, mutect2
- DNM3 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 13/257 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100798815; called by muse, mutect2
- DOCK4 | c.2684G>C p.S895T | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV101448030; called by muse, mutect2, varscan2
- DOCK5 | c.3883G>T p.E1295* | Nonsense Mutation (SNP) | VAF 7/88 reads (8%) | catalogued as COSV52400891; called by muse, mutect2
- DPPA2 | c.721C>A p.L241M | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101524803; called by muse, mutect2, varscan2
- DYM | c.209G>T p.R70L | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.695); catalogued as rs202085847, COSV53982925, COSV99494463; called by muse, mutect2, varscan2
- EXOC4 | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 10/95 reads (11%) | catalogued as COSV99556171; called by muse, mutect2
- FAM135B | c.3700C>T p.R1234W | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757525959, COSV52703914, COSV52737505; called by muse, mutect2, varscan2
- FAM168A | c.86A>G p.Y29C | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99292494; called by muse, mutect2, varscan2
- FAM20A | c.306C>A p.N102K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.029); catalogued as rs1430326707, COSV101646539; called by muse, mutect2
- FAT3 | c.3041A>G p.D1014G | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99972401; called by muse, mutect2
- FAXC | c.842T>C p.M281T | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as COSV101067292; called by muse, mutect2, varscan2
- FCRL1 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100839849, COSV100839927; called by muse, mutect2
- FCRL3 | c.680C>A p.S227Y | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.734); catalogued as rs559562792, COSV100943629, COSV63840816; called by muse, mutect2
- FNTB | c.1208T>A p.I403N | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99863168; called by muse, mutect2, varscan2
- GABRG1 | c.158G>T p.W53L | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54955997, COSV99778949; called by muse, mutect2, varscan2
- GAS2 | c.400del p.E134Kfs*17 | Frame Shift Del (DEL) | VAF 17/166 reads (10%) | catalogued as COSV53413005, COSV99534642; called by mutect2, pindel
- GCNT3 | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV101251885; called by muse, mutect2, varscan2
- GLRB | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as COSV100030246; called by muse, mutect2, varscan2
- GOLGB1 | c.5888A>T p.K1963M | Missense Mutation (SNP) | VAF 52/373 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as rs555643889, COSV100511678; called by muse, mutect2, varscan2
- GPR158 | c.1433C>G p.T478R | Missense Mutation (SNP) | VAF 25/243 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV100894425; called by muse, mutect2, varscan2
- GPR158 | c.2609C>G p.T870R | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as COSV100894427; called by muse, mutect2
- GRIN2A | c.1696C>A p.L566I | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100411390; called by muse, mutect2, varscan2
- GRIN2B | c.3504C>G p.S1168R | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.217); catalogued as rs183502070, COSV101663230, COSV74204949; called by muse, mutect2, varscan2
- HELZ2 | c.6968T>C p.L2323S (on ENST00000467148 / NM_001037335.2; = p.L1754S on NM_033405.3) | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100918853; called by muse, mutect2, varscan2
- HERC2 | c.2208C>G p.N736K | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV99877620; called by muse, mutect2
- HFM1 | c.1474C>T p.Q492* | Nonsense Mutation (SNP) | VAF 24/267 reads (9%) | catalogued as COSV99647072; called by muse, mutect2
- HSPG2 | c.10363A>T p.N3455Y | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101013583; called by muse, mutect2, varscan2
- HTR1E | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as rs778362756, COSV59506609; called by muse, mutect2, varscan2
- IFT80 | c.24A>T p.L8F | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.372); catalogued as rs761978143, COSV100425214; called by muse, mutect2, varscan2
- IQCD | c.437A>C p.Q146P | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV100232536; called by muse, mutect2, varscan2
- ITFG2 | c.635G>C p.C212S | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99958404; called by muse, mutect2, varscan2
- JPH2 | c.2057G>T p.G686V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100881802, COSV100881806; called by muse, mutect2, varscan2
- KCNH3 | c.2722C>T p.L908F | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV99235912; called by muse, mutect2
- KCNH4 | c.2969G>T p.G990V | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV99238049; called by muse, mutect2, varscan2
- KCNT2 | c.1473C>G p.H491Q | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.385); catalogued as COSV99657548; called by muse, mutect2, varscan2
- KCTD8 | c.394C>A p.R132S | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs949124406, COSV100760246; called by muse, mutect2, varscan2
- KHDC3L | c.632G>T p.R211L | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.28); catalogued as COSV100949884, COSV64859553; called by muse, mutect2, varscan2
- KIF7 | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs747191989, COSV67999408; called by muse, mutect2, varscan2
- KLHL2 | c.747G>T p.L249F | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.766); catalogued as COSV99900526; called by muse, mutect2
- KLHL7 | c.293T>G p.L98R (on ENST00000339077 / NM_001031710.3; = p.L50R on NM_018846.5) | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100178545; called by muse, mutect2, varscan2
- LGR6 | c.651G>C p.L217F (on ENST00000367278 / NM_001017403.1; = p.L165F on NM_021636.3) | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99708092; called by muse, mutect2
- LONP2 | c.1696A>G p.R566G | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1254084701, COSV99589626; called by muse, mutect2, varscan2
- LONRF3 | c.2027A>T p.Q676L (on ENST00000371628 / NM_001031855.3; = p.Q635L on NM_024778.5) | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100504759; called by muse, mutect2
- LRFN5 | c.466T>A p.Y156N | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as COSV53241777; called by muse, mutect2, varscan2
- LRP2 | c.8638C>A p.H2880N | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.438); catalogued as COSV99790768; called by muse, mutect2, varscan2
- LRRK2 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100111459; called by muse, mutect2, varscan2
- MAP3K4 | c.3775+1G>A p.X1259_splice | Splice Site (SNP) | VAF 12/92 reads (13%) | catalogued as COSV100815752; called by muse, mutect2, varscan2
- ME1 | c.365G>T p.G122V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100866727; called by muse, mutect2
- MMP16 | c.1601G>A p.G534E | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.014); catalogued as rs747698919, COSV99690914; called by muse, mutect2
- MMS22L | c.1792G>T p.A598S | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.046); catalogued as COSV51516837, COSV99247920; called by muse, mutect2, varscan2
- MORN1 | c.739G>T p.A247S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.815); catalogued as COSV101047643; called by muse, mutect2
- MRPL39 | c.158C>G p.A53G | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100221177; called by muse, mutect2, varscan2
- MTHFD1L | c.2231T>C p.V744A | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); catalogued as COSV100945424; called by muse, mutect2, varscan2
- MYH1 | c.5701C>A p.R1901S | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56846472; called by muse, mutect2
- MYH1 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as COSV99821203; called by muse, mutect2, varscan2
- MYO15A | c.4940T>A p.I1647N | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99234912; called by muse, mutect2, varscan2
- NAV3 | c.4151G>T p.G1384V | Missense Mutation (SNP) | VAF 17/242 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs1036670272, COSV57063508, COSV99887889; called by muse, mutect2
- NSG1 | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV67575404, COSV67575940; called by muse, mutect2, varscan2
- NTRK2 | c.1423G>T p.D475Y (on ENST00000323115 / NM_001369534.1; = p.D491Y on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99459360; called by muse, mutect2, varscan2
- NUTM2G | c.503C>A p.P168H | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100673005; called by muse, mutect2, varscan2
- OBSCN | c.16828G>A p.D5610N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV99486071; called by muse, mutect2, varscan2
- OR2G6 | c.800C>G p.S267C | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV100598361, COSV58574999; called by muse, mutect2
- OR2M2 | c.686G>T p.G229V | Missense Mutation (SNP) | VAF 29/272 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.117); catalogued as COSV100677356, COSV62897910; called by muse, mutect2, varscan2
- OR51S1 | c.900T>A p.S300R | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV100437609; called by muse, mutect2
- OR5T1 | c.223C>A p.L75I | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.242); catalogued as COSV100479281, COSV57302779; called by muse, mutect2
- OR6N1 | c.344T>A p.L115Q | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100625331; called by muse, mutect2, varscan2
- PA2G4 | c.293A>G p.Y98C | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV99918174; called by muse, mutect2, varscan2
- PAK1 | c.1472C>T p.S491L | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99584094; called by muse, mutect2, varscan2
- PARD3B | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100595705; called by muse, mutect2, varscan2
- PC | c.2128G>T p.V710L | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.324); catalogued as COSV100547125, COSV100547206; called by muse, mutect2, varscan2
- PCDHGA6 | c.1264G>A p.V422M | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV99549349; called by muse, mutect2, varscan2
- PCLO | c.3809A>T p.Q1270L | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.058); catalogued as COSV100439357; called by muse, mutect2, varscan2
- PLVAP | c.555C>A p.S185R | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.474); catalogued as COSV99391627, COSV99391904; called by muse, mutect2, varscan2
- PPL | c.4358C>A p.P1453Q | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753654745, COSV52172255; called by muse, mutect2, varscan2
- PPP1R21 | c.1696C>T p.Q566* | Nonsense Mutation (SNP) | VAF 5/67 reads (7%) | catalogued as COSV99682752; called by muse, mutect2
- PRDM5 | c.443A>G p.N148S | Missense Mutation (SNP) | VAF 55/314 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1281753839, COSV99311659; called by muse, mutect2, varscan2
- RIMS2 | c.1396G>C p.V466L (on ENST00000666250 / NM_001348490.2; = p.V274L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.402); catalogued as COSV99212732, COSV99212943; called by muse, mutect2, varscan2
- RNF40 | c.963G>T p.Q321H | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.952); catalogued as COSV100222410; called by muse, mutect2
- RRBP1 | c.3898A>T p.I1300F (on ENST00000377813 / NM_001365613.2; = p.I867F on NM_004587.3) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as COSV99854828; called by muse, mutect2, varscan2
- RYR2 | c.4915G>A p.V1639I | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1477625488, COSV100773345; called by muse, mutect2, varscan2
- SCN11A | c.97A>T p.I33F | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.276); catalogued as COSV100182914; called by muse, mutect2, varscan2
- SDK1 | c.4835A>G p.Q1612R | Missense Mutation (SNP) | VAF 62/422 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.275); catalogued as COSV101270035; called by muse, mutect2
- SI | c.770C>G p.T257R | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.897); catalogued as COSV100017556; called by muse, mutect2
- SLC8A3 | c.424G>T p.G142C | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100776434; called by muse, mutect2, varscan2
- SLCO1B3 | c.659C>A p.P220Q | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53941882, COSV99682441; called by muse, mutect2
- SOX10 | c.1031C>G p.T344R | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100704227, COSV62806935; called by muse, mutect2, varscan2
- SPICE1 | c.1322A>T p.E441V | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99871942; called by muse, mutect2, varscan2
- SPTA1 | c.5664+1G>T p.X1888_splice | Splice Site (SNP) | VAF 36/173 reads (21%) | catalogued as COSV100935789, COSV63760897; called by muse, mutect2, varscan2
- STAB2 | c.2809G>T p.E937* | Nonsense Mutation (SNP) | VAF 14/116 reads (12%) | catalogued as COSV101186467, COSV66343565; called by muse, varscan2
- STARD3NL | c.122A>T p.E41V | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as rs1360538408, COSV99151616; called by muse, mutect2, varscan2
- SYN1 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757776027, COSV99928186; called by muse, mutect2
- TAOK1 | c.885G>T p.Q295H | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99914949; called by muse, mutect2, varscan2
- TAS2R9 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.095); catalogued as COSV53689137; called by muse, mutect2, varscan2
- TBL2 | c.804G>T p.E268D | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as COSV99979793; called by muse, mutect2, varscan2
- TCP11L2 | c.712C>T p.Q238* | Nonsense Mutation (SNP) | VAF 26/188 reads (14%) | catalogued as COSV100135642; called by muse, mutect2, varscan2
- TMEM74 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52464262; called by muse, mutect2
- TRIM56 | c.2140G>T p.D714Y | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV100047897; called by muse, mutect2, varscan2
- TSKU | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV100290278; called by muse, mutect2
- TTC3 | c.406G>T p.D136Y | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100696169; called by muse, mutect2, varscan2
- TTN | c.48686C>A p.T16229K (on ENST00000591111; = p.T8805K on NM_003319.4) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | PolyPhen benign (0.288); catalogued as COSV100635415; called by muse, mutect2, varscan2
- TTN | c.35764A>C p.T11922P (on ENST00000591111; = p.T4498P on NM_003319.4) | Missense Mutation (SNP) | VAF 47/208 reads (23%) | PolyPhen benign (0); catalogued as COSV100635416; called by muse, mutect2, varscan2
- WASHC5 | c.1024C>T p.Q342* | Nonsense Mutation (SNP) | VAF 17/108 reads (16%) | catalogued as rs1296153120, COSV100573156; called by muse, mutect2, varscan2
- YPEL3 | c.44A>T p.D15V (on ENST00000398838 / NM_001145524.2; = p.D53V on NM_031477.5) | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as COSV99661860; called by muse, mutect2, varscan2
- ZBTB20 | c.1153A>T p.T385S (on ENST00000474710 / NM_001164342.2; = p.T312S on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV100615504; called by muse, mutect2
- ZNF107 | c.190G>C p.V64L | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100788574; called by muse, mutect2
- ZNF572 | c.746G>A p.C249Y | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100074174; called by muse, mutect2, varscan2
- ZNF665 | c.135A>C p.K45N (on ENST00000600412; = p.K110N on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); catalogued as COSV101128947; called by muse, mutect2, varscan2
- AKAP6 | c.973dup p.V325Gfs*18 | Frame Shift Ins (INS) | VAF 9/83 reads (11%) | called by mutect2, pindel, varscan2
- CCDC141 | c.2448_2456del p.E816_G818del | In Frame Del (DEL) | VAF 21/98 reads (21%) | called by mutect2, pindel, varscan2
- COL5A2 | c.3633+1del p.X1211_splice | Splice Site (DEL) | VAF 36/177 reads (20%) | called by mutect2, pindel, varscan2
- LHX1 | c.321C>G p.I107M | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.368); called by muse, mutect2
- MOK | c.537_559del p.Y179* | Nonsense Mutation (DEL) | VAF 41/138 reads (30%) | called by mutect2, pindel, varscan2
- MRC1 | c.1150C>A p.Q384K | Missense Mutation (SNP) | VAF 28/256 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.683); called by muse, mutect2
- PCDHB6 | c.1482dup p.H495Afs*179 | Frame Shift Ins (INS) | VAF 37/277 reads (13%) | called by mutect2, pindel, varscan2
- TRAV16 | c.7C>G p.P3A | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRBV27 | c.310C>G p.Q104E | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- TTN | c.22238del p.P7413Hfs*4 (on ENST00000591111; = p.P6486Hfs*4 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | called by mutect2, pindel, varscan2
- UTP20 | c.3146_3149del p.Q1049Lfs*8 | Frame Shift Del (DEL) | VAF 30/218 reads (14%) | called by mutect2, pindel, varscan2
- ZNF527 | c.390del p.W130* | Frame Shift Del (DEL) | VAF 32/110 reads (29%) | called by mutect2, pindel, varscan2
- ZNF594 | c.2185del p.L729Cfs*53 | Frame Shift Del (DEL) | VAF 26/253 reads (10%) | called by mutect2, varscan2
- AAAS | c.6C>T p.C2= | Silent (SNP) | VAF 37/347 reads (11%) | catalogued as rs1375707105, COSV99267176; called by muse, mutect2, varscan2
- ADAMTS3 | c.3471C>T p.H1157= | Silent (SNP) | VAF 22/197 reads (11%) | catalogued as rs770557731, COSV99712420; called by muse, mutect2, varscan2
- AHNAK2 | c.9075C>T p.D3025= | Silent (SNP) | VAF 124/347 reads (36%) | catalogued as COSV100319308; called by muse, mutect2, varscan2
- ATF7IP | c.3498G>A p.L1166= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV99662326; called by muse, mutect2, varscan2
- CCDC141 | c.3213G>A p.Q1071= | Silent (SNP) | VAF 43/230 reads (19%) | catalogued as COSV99837662; called by muse, mutect2, varscan2
- CES2 | c.594C>T p.Y198= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV100399474; called by muse, mutect2, varscan2
- CLVS2 | c.558C>A p.G186= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV99253773; called by muse, mutect2, varscan2
- COL3A1 | c.3978T>G p.V1326= | Silent (SNP) | VAF 38/181 reads (21%) | catalogued as COSV100483927; called by muse, mutect2, varscan2
- COL9A1 | c.1020G>A p.K340= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV100295905; called by muse, mutect2, varscan2
- CR2 | c.2352T>A p.P784= | Silent (SNP) | VAF 38/152 reads (25%) | catalogued as COSV100889724; called by muse, mutect2, varscan2
- CXCR6 | c.567T>A p.T189= | Silent (SNP) | VAF 21/119 reads (18%) | catalogued as COSV99945461; called by muse, mutect2, varscan2
- CYP2A7 | c.229C>A p.R77= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs534988246; called by mutect2, varscan2
- DMTF1 | c.63G>A p.L21= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as rs752360561, COSV100487552; called by muse, mutect2, varscan2
- DNAH8 | c.10992G>A p.L3664= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV100547469; called by muse, mutect2, varscan2
- DNER | c.1533C>T p.S511= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as rs141484245; called by muse, mutect2, varscan2
- ESR1 | c.48T>C p.H16= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV99241862; called by muse, mutect2, varscan2
- FAM120B | c.1101G>A p.V367= | Silent (SNP) | VAF 33/335 reads (10%) | catalogued as COSV99380148; called by muse, mutect2
- FRMPD4 | c.2133G>T p.V711= | Silent (SNP) | VAF 35/214 reads (16%) | catalogued as COSV101044339; called by muse, mutect2, varscan2
- GALNT8 | c.354C>G p.L118= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV99363349; called by muse, mutect2, varscan2
- GDF3 | c.642G>T p.V214= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as rs149033500, COSV100325454, COSV61712804; called by muse, mutect2
- GMEB2 | c.396C>T p.H132= | Silent (SNP) | VAF 15/140 reads (11%) | catalogued as COSV99823930; called by muse, mutect2, varscan2
- GPC5 | c.585G>T p.R195= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as rs748810958, COSV100996362; called by muse, mutect2
- GPR63 | c.891G>A p.Q297= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100013621; called by muse, mutect2, varscan2
- ITPR2 | c.6021C>T p.I2007= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as rs373259914; called by muse, mutect2, varscan2
- LRIG3 | c.1098G>A p.L366= | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as COSV100292910; called by muse, mutect2, varscan2
- NIBAN1 | c.1452T>C p.Y484= | Silent (SNP) | VAF 14/162 reads (9%) | catalogued as COSV100836665; called by muse, mutect2
- NXPE1 | c.486C>A p.G162= (on ENST00000424269; = p.G20= on NM_152315.5) | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV99321222; called by muse, mutect2, varscan2
- OPRD1 | c.669G>A p.V223= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV99330600; called by muse, mutect2
- OR4D6 | c.174T>A p.P58= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100271889; called by mutect2, varscan2
- OR5H15 | c.402C>A p.A134= | Silent (SNP) | VAF 16/294 reads (5%) | catalogued as COSV100736802; called by muse, mutect2
- P2RY2 | c.486G>T p.L162= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV100232913; called by muse, mutect2, varscan2
- PAK3 | c.243T>C p.H81= | Silent (SNP) | VAF 44/165 reads (27%) | catalogued as COSV99458566; called by muse, mutect2, varscan2
- PCDH15 | c.786T>A p.G262= | Silent (SNP) | VAF 24/199 reads (12%) | catalogued as COSV100229402; called by muse, mutect2, varscan2
- PCDH8 | c.2052C>A p.R684= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV100132083, COSV100132141; called by muse, mutect2
- PNLDC1 | c.1503C>A p.V501= | Silent (SNP) | VAF 15/141 reads (11%) | catalogued as COSV99277979; called by muse, mutect2, varscan2
- PPP1R3A | c.234A>G p.K78= | Silent (SNP) | VAF 30/190 reads (16%) | catalogued as COSV99494729; called by muse, mutect2, varscan2
- PRB1 | c.729C>G p.P243= | Silent (SNP) | VAF 20/320 reads (6%) | catalogued as rs1419337885, COSV99556150; called by muse, mutect2
- PSMC1 | c.249A>G p.E83= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV99728601; called by muse, mutect2, varscan2
- PTPRD | c.2220G>A p.Q740= | Silent (SNP) | VAF 26/186 reads (14%) | catalogued as COSV61930383; called by muse, mutect2, varscan2
- REPS1 | c.1017A>T p.T339= | Silent (SNP) | VAF 25/220 reads (11%) | catalogued as COSV99239145; called by muse, mutect2, varscan2
- RIT2 | c.253C>A p.R85= | Silent (SNP) | VAF 38/356 reads (11%) | catalogued as rs777569822, COSV56306812, COSV99951309; called by muse, mutect2
- ROS1 | c.6397T>C p.L2133= | Silent (SNP) | VAF 29/274 reads (11%) | catalogued as rs765386753, COSV100877861; called by muse, mutect2, varscan2
- RPIA | c.438C>T p.L146= | Silent (SNP) | VAF 15/119 reads (13%) | catalogued as rs1489422350, COSV99376567; called by muse, mutect2, varscan2
- SPTB | c.2515C>T p.L839= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV101072485; called by muse, mutect2, varscan2
- STRC | c.4896A>G p.Q1632= | Silent (SNP) | VAF 4/69 reads (6%) | catalogued as rs1448281022, COSV100294730; called by muse, mutect2
- TENM4 | c.5310G>T p.L1770= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV99580684; called by muse, mutect2, varscan2
- TEX15 | c.6264T>C p.F2088= (on ENST00000256246; = p.F2471= on NM_001350162.2) | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as COSV99822370; called by muse, mutect2, varscan2
- TGM6 | c.1842C>T p.G614= | Silent (SNP) | VAF 31/352 reads (9%) | catalogued as rs764934493, COSV99172955; called by muse, mutect2
- TRPC1 | c.666T>C p.S222= (on ENST00000476941 / NM_001251845.2; = p.S188= on NM_003304.4) | Silent (SNP) | VAF 11/119 reads (9%) | catalogued as COSV99859482; called by muse, mutect2
- TRRAP | c.4914C>T p.L1638= (on ENST00000359863 / NM_001244580.1; = p.L1620= on NM_003496.3) | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV100722751, COSV100723220; called by muse, mutect2, varscan2
- TTLL5 | c.1101G>T p.V367= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as COSV100092062; called by muse, mutect2, varscan2
- TTN | c.5361C>T p.H1787= (on ENST00000591111; = p.H1741= on NM_003319.4) | Silent (SNP) | VAF 39/154 reads (25%) | catalogued as rs958776952, COSV100635418; called by muse, mutect2, varscan2
- ZC3H13 | c.1692G>A p.R564= | Silent (SNP) | VAF 22/122 reads (18%) | catalogued as COSV99669107; called by muse, mutect2, varscan2
- ZDHHC3 | c.474C>T p.P158= | Silent (SNP) | VAF 75/429 reads (17%) | catalogued as COSV99943709; called by muse, mutect2, varscan2
- ZNF471 | c.876T>C p.C292= | Silent (SNP) | VAF 23/264 reads (9%) | catalogued as COSV100340948; called by muse, mutect2
- ZNF536 | c.3759G>T p.R1253= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs141558241; called by mutect2, varscan2
- AL353804.4 | chrX:73821477 A>T | 3'Flank (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- DDX41 | c.*217A>C | 3'UTR (SNP) | VAF 7/79 reads (9%) | catalogued as COSV100394586; called by muse, mutect2
- MAGEA5 | n.139C>G | RNA (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- NALCN | c.1765-4914C>A | Intron (SNP) | VAF 8/78 reads (10%) | catalogued as COSV99218518; called by muse, mutect2, varscan2
- NR2E1 | c.25+1330G>T | Intron (SNP) | VAF 4/14 reads (29%) | catalogued as COSV64562582; called by muse, mutect2
- SNORD115-36 | n.1G>A | RNA (SNP) | VAF 34/410 reads (8%) | called by muse, mutect2
- SNORD116-19 | n.51G>A | RNA (SNP) | VAF 52/443 reads (12%) | catalogued as rs1372584969; called by muse, mutect2, varscan2
- SSPOP | n.7555C>T | RNA (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100023101; called by muse, mutect2
